TCGA case TCGA-DX-AB2J — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Retroperitoneum and peritoneum; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5d9608fd-e3eb-4bf9-911f-7656d6814b98

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 71 years; Vital status: Dead; Days to death: 1,235 days (3.4 years).

Diagnoses (2)
1. Undifferentiated sarcoma (the primary disease): ICD-O-3 morphology code: 8805/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 71.6 years (26,154 days); Year of diagnosis: 2006; Metastasis at diagnosis: No Metastasis; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 13.3; Tumor length measurement: 19.3; Tumor width measurement: 18.7.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Necrosis percent: 30; Necrosis present: Yes; Tumor depth descriptor: Deep.
2. Thecoma, NOS: ICD-O-3 morphology code: 8600/0; Tissue or organ of origin: Ovary; Laterality: Right; Classification of tumor: Prior primary; Age at diagnosis: 51.5 years (18,818 days); Days to diagnosis: -7,336 days (-20.1 years).

Follow-up (1 entry)
- Days to follow up: 1,235 days (3.4 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-AB2J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 990 mg.
  Slide TCGA-DX-AB2J-01A-01-TSA: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DX-AB2J-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-AB2J-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Pleomorphic 'MFH' / Undifferentiated pleomorphic sarcoma; Margin status: Positive; Tumor total necrosis: Moderate Necrosis (>=10, <50%); Disease multifocal indicator: No; Locoregional recurrence indicator: No; Metastatic disease confirmed: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower abdominal/Pelvic - Pelvic.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Ovary; Other malignancy histological type: Thecoma.
- Other malignancy form, Surgery: Other malignancy surgery type: Tah/bso.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,235 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,235 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,235 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-AB2J-01A-11D-A386-01): tumor purity 0.97, ploidy 2.02, whole-genome doublings 0.
